CCDI case PBBKTU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fe64fbfc-4437-423d-97a8-fee7e39be6d4

Demographics
Sex at birth: male; Vital status: Dead.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.9 years (3,627 days).

Biospecimens (3 samples)
- Sample 0DBD14: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBD15: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DBD1C: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
